Gene-level copy-number profile of tumor specimen TCGA-IB-A7LX-01A from TCGA case TCGA-IB-A7LX, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 57.2 years (20,898 days).
Specimen TCGA-IB-A7LX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.92656b0b-848f-4665-bd31-c70f6c313573.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-A7LX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/04119792-03b4-4ef3-85ac-ee1f43ed53a3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 67; copy number 1: 940; copy number 2: 12,755; copy number 3: 17,995; copy number 4: 23,549; copy number 5: 2,441; copy number 6: 339; copy number 7: 1,446; copy number 8: 124; copy number 9: 21; copy number 10: 9; copy number 11: 83; copy number 14: 46; copy number 18: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IB-A7LX-01A-12D-A36N-01): tumor purity 0.72, ploidy 1.62, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:240,775,514–241,357,230, 1 gene (within-gene range 0–4): RGS7.
- chr1:240,998,451–241,132,346, 2 genes: AL590682.1, MIR3123.
- chr9:20,658,309–23,438,700, 64 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 163 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:99,174,744–102,369,827, 29 genes, copy number 9–11: BDH2P1, FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1, PRDM13, Y_RNA, MCHR2, MCHR2-AS1, NPM1P38, AL080285.2, PRDX2P4, AL080285.1, SIM1, SIM1-AS1, ASCC3, Z86062.1, AL133338.1, AL133338.2, GRIK2, ACTG1P18, AP002528.1, AP002530.1, AL357139.2.
- chr6:129,439,485–129,576,047, 1 gene, copy number 11 (within-gene range 2–11): AL356124.1.
- chr6:132,814,569–135,813,990, 56 genes, copy number 10–14 (within-gene range 2–14): RPS12, SNORD101, SNORD100, SNORA33, HMGB1P13, AL137783.1, LINC00326, RPL23AP46, AL591115.1, MTCYBP4, EYA4, AL024497.1, AL024497.2, TARID, HSPE1P21, AL450270.1, FTH1P26, LINC01312, TCF21, TBPL1, AL035699.1, SLC2A12, AL449363.1, AL449363.2, HMGA1P7, RN7SL408P, SGK1, RPS29P32, RNA5SP218, Y_RNA, AL355881.1, KRT8P42, LINC01010, Z84486.1, CHCHD2P4, CT69, AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1, MEMO1P2, ALDH8A1, AL445190.1, HBS1L, MIR3662, AL353596.1, MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2, Y_RNA, LINC00271.
- chr6:135,628,787–138,383,486, 51 genes, copy number 11 (within-gene range 2–11): AL035604.1, HMGB1P17, AL133319.1, PDE7B, AL360178.1, AL360178.2, AL138828.1, COX5BP2, AL138828.2, MTFR2, BCLAF1, AL023284.1, AL023284.4, MAP7, AL023284.3, AL023284.2, NDUFS5P1, RN7SKP299, AL024508.1, MAP3K5, MAP3K5-AS1, RNA5SP219, AL121933.2, PEX7, AL121933.1, AL365223.1, SLC35D3, Y_RNA, RPL35AP3, NHEG1, AL135902.1, IL20RA, IL22RA2, IFNGR1, OLIG3, BTF3L4P3, AL356234.2, AL356234.3, AL356234.1, LINC02539, Y_RNA, WAKMAR2, TNFAIP3, AL591468.1, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1, SMIM28.
- chr7:89,882,353–91,210,590, 19 genes, copy number 11 (within-gene range 5–11): STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1.
- chr7:147,080,934–147,378,121, 4 genes, copy number 18: CNTNAP2-AS1, DUTP3, RANP2, MIR548F4.
- chr18:4,264,602–4,459,458, 3 genes, copy number 9 (within-gene range 5–9): DLGAP1-AS5, AP005208.1, ELOCP27.

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
